Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8ZX, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8ZX-06A (Metastatic).

[page 1 of 5]
Sample

(Tissue) Collected

Received

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: Plastic Surgery

Copy To: Tissue banking

Report to Cancer Registry

1CD-0-3

Melanoma, Nos 8720/3

Site: lymph node, axilla C77.3

HISTOPATHOLOGY REPORT

**SUPPLEMENTARY REPORT

**

hw 5/30/14

LAB No:

CASE HISTORY:

Metastatic malignant melanoma in left adrenal gland and left axillary lymph nodes.

MACROSCOPIC:

1. Received fresh and unfixed for tissue banking , an adrenal gland with surrounding perinephric fat, in total 7 x 6 x 2cm. The medulla of the adrenal gland contains an irregular yellow grey tumour deposit, 2 x 1.2cm. A = Tissue Bank sample of tumour, B = Tissue Bank sample of normal adrenal gland.
2. Received fresh and unfixed for tissue banking , a left axillary resection. It comprises a skin ellipse (14 x 1.3cm) with underlying fat and skeletal muscle, forming a triangular structure, 14 x 3 x up to 14.5cm deep. 2A = Tissue Bank sample of enlarged lymph node, 2B = Tissue Bank sample of skeletal muscle. Arising towards the centre of the skin ellipse in the underlying fat is a grey tumour nodule, approximately 1.7cm diameter. Part has been tissue banked. 2C+2D = further samples from this nodule, 2E = adjacent lymph node, 2F+2G = large lymph node x one, 2H = lymph node x one, 2I+2J = lymph node x one, 2K = enlarged, obviously involved, lymph node close to muscle, 2L = near by lymph node x one, 2M = near by lymph node x one, 2N = lymph node x one, 2P = enlarged lymph node x one. It contains a small grey nodule. 2Q = lymph node x one, 2R = lymph node x one, 2S = lymph node x one.
3. Lymph node, Level 2. Fatty fragment, 1.2cm max. All embedded.
4. Lymph node, Level 3. Fatty tissue, 2.8 x 2.3 x 0.7cm. All embedded.

MICROSCOPY:

1. A malignant, focally necrotic, tumour composed of sheets and nests of polygonal epithelioid cells with large nuclei, prominent eosinophilic nucleoli and abundant eosinophilic cytoplasm. Some cells have a yellowish cytoplasmic hue, but definitive melanin is not recognised. The tumour is largely confined to the adrenal medulla, focally extending into the cortex with a possible focus of extracapsular spread (which is difficult to assess due to the fragility of tumour).

Tissue Bank samples:

- A. Metastatic malignant melanoma.
- B. Normal adrenal parenchyma.

[page 2 of 5]
2. Thirteen lymph nodes have been recovered and six of them show metastatic deposits of malignant melanoma. The tumour cells contain brown pigment within their cytoplasm. The largest nodal deposit is approximately 18 mm in maximum diameter. There is no evidence of extracapsular spread.

Tissue Bank samples:

- A. Metastatic malignant melanoma.
- B. Normal skeletal muscle.

3. Fibrofatty tissue is present but there is no evidence of a lymph node. There is no evidence of malignancy.

4. The one lymph node recovered contains deposits of metastatic malignant melanoma. There is no evidence of extracapsular spread.

DIAGNOSIS:

- 1. LEFT ADRENAL GLAND; METASTATIC MALIGNANT MELANOMA
- 2. LEFT AXILLARY RESECTION
LYMPH NODES, LEFT AXILLA: METASTATIC MALIGNANT MELANOMA (6/13)
- 3. LEVEL II LYMPH NODES (LEFT AXILLA): FIBROFATTY TISSUE ONLY, NEGATIVE FOR NEOPLASIA.
- 4. LEVEL III (LEFT AXILLARY LYMPH NODE): METASTATIC MALIGNANT MELANOMA (1/1).

REPORTED BY:

, Consultant Histopathologist

REPORT DATE:

SUPPLEMENTARY REPORT:

The specimen was sent to for BRAF testing. Their report reads:

Sequencing analysis of the BRAF gene has revealed the presence of a mutation within codon 600 of BRAF gene.

COBAS technique does not differentiated between V600E and V600K.

MELANOMA: PATHOGENIC MUTATION WITHIN CODON 600 OF BRAF.

REPORTED BY:

Consultant Histopathologist

Sample (Fine Needle Aspirate) Collected
Received

Non Gynae Fine Needle Aspirate

Non Gynae Fine Needle Aspirate

ADDRESS FOR REPORT: Plastic Surgery,
Copy To: n/a
Report to Cancer Registry
CYTOPATHOLOGY REPORT

LAB No:

[page 3 of 5]
CASE HISTORY:

Melanoma left axilla. Axillary dissection . ?Recurrence.

MACROSCOPIC:

3 air dried slides dated

MICROSCOPY:

Numerous markedly pleomorphic, malignant epithelioid cells are present, many of which contain intracytoplasmic pigment granules. Appearances are entirely in keeping with metastatic melanoma.

DIAGNOSIS:

LEFT SUPRACLAVICULAR LYMPH NODE FNA: METASTATIC MELANOMA

REPORTED BY:

, Consultant Histopathologist

REPORT DATE:

Sample

(Tissue) Collected

Received

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: PLASTIC SURGERY

Copy To: n/a

Report to Cancer Registry

HISTOPATHOLOGY REPORT

**SUPPLEMENTARY REPORT

**

LAB No:

CASE HISTORY:

Recurrent metastatic melanoma. 1st axillary dissection . Now recurrent nodule on PET CT (8). Neck dissection for macroscopic disease.

MACROSCOPIC:

1. Left external jugular vein and nodes. Strip of fibrofatty tissue (7 cm in length up to 1.5 cm diameter) and separate fatty frags together 1.5 cm. The main specimen bears a suture. Main specimen in blocks A&B with separate frags in C.
2. Left level 2. Fibrofatty tissue (5 x 3 x 1.5 cm) which appears to contain salivary gland 3 x 2.5 x 1 cm (sampled in A&B).
3. Left level 3. Fibrofatty tissue 4.5 x 2.5 x 1.5 cm.
4. Left level 4. Fatty tissue 3 x 2.5 x 1 cm.
5. Left level 5A. Fibrofatty tissue 4 x 2.5 x 1 cm. Breadsliced in three cassettes.
6. Left level 5B. Nodular mass of lymph nodes (10 x 6.5 x 3.5 cm) bearing sutures and small metal clips. One end of the specimen has been partially inked green and a sample removed from an underlying lymph node. Remainder of specimen inked black. Slice from tissue banked node in A. Slicing shows multiple lymph nodes replaced by pale tumour, the largest individual metastasis up to 21 mm diameter. Other nodes are matted together to form a nodular mass up to 4 cm

[page 4 of 5]
diameter (C&D). Two adjacent involved nodes in E.
7. Left axilla. Firm fibrotic tissue 2 x 1.5 x 1.7 cm.
8. Tissue left axilla. Fibrofatty tissue 3.5 x 2 x 1 cm.

MICROSCOPY:

1. Vein, parotid tissue and 4 lymph nodes with no evidence of malignancy.
2. 24 lymph nodes with no evidence of malignancy.
3. 15 lymph nodes with no evidence of malignancy.
4. 10 lymph nodes with no evidence of malignancy.
5. One lymph node with no evidence of malignancy.
6. 20 lymph nodes are present, 9 of which are extensively replaced by highly pleomorphic and focally necrotic metastatic malignant melanoma (including the node sampled for tissue banking). No definite extracapsular spread is seen.
7. Dense fibrous scar tissue and one atrophic lymph node with no evidence of malignancy.
8. Dense fibrous scar tissue, atrophic muscle and one lymph node with no evidence of malignancy.

DIAGNOSIS:

1-6. LEFT NECK DISSECTION (LEVELS 2 TO 5B): METASTATIC MALIGNANT MELANOMA IN 9 OF 74 LYMPH NODES, ALL IN LEVEL 5B, LARGEST METASTASIS 21 MM, NO DEFINITE EXTRACAPSULAR SPREAD
7&8. LEFT AXILLARY TISSUE: SCAR TISSUE AND 2 NEGATIVE NODES

REPORTED BY:

Consultant Histopathologist

REPORT DATE:

SUPPLEMENTARY REPORT:

Following review, further levels were cut from one of the involved lymph nodes in level 5B. This shows evidence of extracapsular spread.

REPORTED BY:

, Consultant Histopathologist.

Sample	(Tissue) Collected	Received
--------	--------------------	----------

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: GENERAL SURGERY

Copy To: n/a

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

Hot appendix on PET scan. Previous melanoma excision.

MACROSCOPIC:

[page 5 of 5]
1. Appendix. Appendix with attached mesoappendix 4 x 0.5 cm.
Serosal surface has injected vessels.
2. Right inguinal node biopsy. Piece of tissue 1.5 x 1.1 x 0.5 cm.

MICROSCOPY:

1. Appendix which shows fibrous luminal obliteration. There is no evidence of appendicitis or neoplasia.
2. The lymph node shows follicular lymphoid hyperplasia with sinus histiocytosis. There is no evidence of neoplasia.

DIAGNOSIS:

1. APPENDIX: NEGATIVE FOR APPENDICITIS AND NEOPLASIA.
2. RIGHT INGUINAL LYMPH NODE BIOPSY: NEGATIVE FOR NEOPLASIA.

REPORTED BY:

Consultant Histopathologist.

REPORT DATE:

Resigned redacted copy.

Criteria: lw 5/30/14	Yes	No

Source: NCI Genomic Data Commons file 4343177d-276e-4ab7-9dd8-485cb58794ef (TCGA-WE-A8ZX.9FF6D78B-6DEA-4780-A790-5E1A9C6AC432.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).